Somatic mutation profile of tumor specimen TCGA-DX-A48L-01A (aliquot TCGA-DX-A48L-01A-11D-A307-09) from TCGA case TCGA-DX-A48L, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 49.6 years (18,113 days).
Specimen TCGA-DX-A48L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 884382a7-8f9f-4f00-aa19-b32f05f31f1b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A48L-10A (Blood Derived Normal), aliquot TCGA-DX-A48L-10A-01D-A307-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/138d5e3d-3dbb-4687-a253-75ea48d291f4

The open-access MAF lists 53 somatic variants for this specimen: 36 protein-altering or splice-affecting, 14 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 14, Frame Shift Del 3, Nonsense Mutation 3, 3'Flank 1, RNA 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC12 | c.1825C>A p.Q609K | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100253461; called by muse, mutect2, varscan2
- ARHGEF6 | c.453G>T p.K151N | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.638); catalogued as COSV99166833; called by muse, mutect2, varscan2
- ARMH3 | c.799C>A p.Q267K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.057); catalogued as rs1301593069, COSV64233381; called by muse, mutect2, varscan2
- BCOR | c.976C>A p.P326T | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.873); catalogued as rs1475754838, COSV100654432; called by muse, mutect2
- CDK5R1 | c.889G>T p.D297Y | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as rs769214004, COSV100531933; called by muse, varscan2
- CEBPE | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 64/124 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1236429877, COSV52829414, COSV52829550; called by muse, mutect2, varscan2
- CTC1 | c.1451A>G p.H484R | Missense Mutation (SNP) | VAF 18/523 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.059); catalogued as rs1469740896, CM151716, COSV100236930; called by muse, mutect2
- DAB2 | c.1096T>C p.F366L | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100298507; called by muse, mutect2
- DMD | c.8449C>T p.L2817F | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100630027; called by muse, mutect2, varscan2
- ELAC2 | c.1786C>A p.Q596K | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV100546383; called by muse, mutect2
- EYS | c.1636G>C p.D546H | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV100677323; called by muse, mutect2, varscan2
- FBXO9 | c.824C>T p.T275I | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV99762701; called by muse, mutect2, varscan2
- GLB1L2 | c.1316C>A p.S439* | Nonsense Mutation (SNP) | VAF 23/25 reads (92%) | catalogued as COSV100335559; called by muse, mutect2, varscan2
- GPR137B | c.808G>C p.D270H | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100858433; called by muse, mutect2, varscan2
- GTSF1L | c.210A>T p.E70D | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV100883967; called by muse, mutect2
- HDAC4 | c.2238C>A p.F746L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs753482334, COSV61860486, COSV61869956; called by muse, mutect2, varscan2
- KIAA1109 | c.5944G>A p.D1982N | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); catalogued as COSV52678355, COSV99193981; called by muse, mutect2, varscan2
- MAP4K5 | c.184A>G p.I62V | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.982); catalogued as COSV99184916; called by muse, mutect2, varscan2
- MYH8 | c.5494G>A p.E1832K | Missense Mutation (SNP) | VAF 34/502 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101238993; called by muse, mutect2
- OBSCN | c.15826C>T p.R5276C | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs564170262, COSV52791013; called by muse, mutect2
- OR6K3 | c.149T>A p.I50N (on ENST00000368146; = p.I34N on NM_001005327.2) | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV63745729; called by muse, mutect2
- PIAS1 | c.734G>T p.R245L | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764996234, COSV51030416, COSV99986783; called by muse, mutect2, varscan2
- RBBP8 | c.2429G>T p.G810V | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59091014; called by muse, mutect2, varscan2
- SCN2A | c.5030T>A p.F1677Y | Missense Mutation (SNP) | VAF 111/228 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV99334083; called by muse, mutect2, varscan2
- SPECC1 | c.3075G>T p.L1025F | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99823127; called by muse, mutect2, varscan2
- SPRYD3 | c.826C>A p.L276M | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV100036649; called by muse, mutect2
- TANC2 | c.4534G>T p.G1512* | Nonsense Mutation (SNP) | VAF 3/27 reads (11%) | catalogued as COSV101267335, COSV101267663; called by muse, mutect2
- TPCN2 | c.1043G>A p.G348E | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV99594089; called by muse, mutect2, varscan2
- TRPM6 | c.5369C>A p.S1790Y | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100667178; called by muse, mutect2
- YES1 | c.1270A>T p.N424Y | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV100100066; called by muse, mutect2, varscan2
- ZDBF2 | c.4121T>C p.F1374S | Missense Mutation (SNP) | VAF 49/51 reads (96%) | SIFT tolerated (0.12); PolyPhen benign (0.112); catalogued as rs762568697, COSV100985726; called by muse, mutect2, varscan2
- ZNF595 | c.1513G>T p.E505* | Nonsense Mutation (SNP) | VAF 22/25 reads (88%) | catalogued as COSV100227980; called by muse, mutect2, varscan2
- PKD1 | c.5648_5650del p.A1883del | In Frame Del (DEL) | VAF 28/76 reads (37%) | called by pindel, varscan2
- RB1 | c.1450_1451del p.M484Vfs*8 | Frame Shift Del (DEL) | VAF 24/36 reads (67%) | called by pindel, varscan2
- TIA1 | c.898del p.I300Lfs*89 (on ENST00000433529 / NM_001351511.1; = p.I289Lfs*89 on NM_022037.4 and 9 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 37/57 reads (65%) | called by mutect2, pindel, varscan2
- WRAP53 | c.82del p.H28Tfs*5 | Frame Shift Del (DEL) | VAF 258/357 reads (72%) | called by mutect2, pindel, varscan2
- ARHGAP44 | c.927C>T p.C309= | Silent (SNP) | VAF 19/356 reads (5%) | catalogued as rs753277638, COSV99311770; called by muse, mutect2
- CFH | c.1920T>C p.N640= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV100810386; called by muse, mutect2, varscan2
- DNAH2 | c.5817C>A p.I1939= | Silent (SNP) | VAF 15/458 reads (3%) | catalogued as COSV101209665, COSV66728054; called by muse, mutect2
- ENTPD4 | c.1683C>A p.V561= | Silent (SNP) | VAF 9/102 reads (9%) | catalogued as COSV100652852; called by muse, mutect2
- GPRIN1 | c.1485C>T p.G495= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as rs147157849, COSV99992319; called by muse, mutect2, varscan2
- HMGN5 | c.180C>A p.A60= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as rs1462069697, COSV63916442; called by muse, mutect2, varscan2
- LHCGR | c.1602C>A p.L534= | Silent (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- PKHD1L1 | c.4776C>T p.L1592= | Silent (SNP) | VAF 25/45 reads (56%) | catalogued as rs762277155, COSV65738245; called by muse, mutect2, varscan2
- POU3F1 | c.723G>A p.V241= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV100884740; called by mutect2, varscan2
- PRDM2 | c.1728T>G p.T576= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV99343041; called by muse, mutect2, varscan2
- RHPN2 | c.1260C>T p.H420= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs374714452; called by muse, mutect2, varscan2
- SMG1 | c.3645G>A p.K1215= | Silent (SNP) | VAF 94/217 reads (43%) | catalogued as rs763786508, COSV101247059; called by muse, mutect2, varscan2
- TKFC | c.1641C>T p.I547= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as rs1447177808, COSV53650955, COSV99582779; called by muse, mutect2, varscan2
- ZNF335 | c.825C>T p.A275= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as rs797046125, COSV100533565; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CAPN1 | chr11:65214071 G>T | 3'Flank (SNP) | VAF 8/116 reads (7%) | catalogued as rs1451465107; called by muse, mutect2
- SLC22A17 | n.832T>C | RNA (SNP) | VAF 21/35 reads (60%) | catalogued as COSV99249144; called by muse, mutect2, varscan2
- STRN3 | c.282+11252C>A | Intron (SNP) | VAF 18/111 reads (16%) | catalogued as rs1214688306, COSV62578594; called by muse, mutect2, varscan2
